Somatic mutation profile of tumor specimen 0DL0JE from CCDI case PBBYZB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 6.1 years (2,214 days).
Specimen 0DL0JE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1500f83b-e316-4177-b167-42131eb4d4e0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DL0IY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ba0f18a-73ef-442d-a187-7406dc111f0b

The open-access MAF lists 29 somatic variants for this specimen: 16 protein-altering or splice-affecting, 7 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 7, 5'UTR 2, 3'UTR 1, RNA 1, 5'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3C11 | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 360/866 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.879); catalogued as rs1057519904; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DTX4 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 82/1022 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as rs780181571; called by muse, mutect2
- GPC6 | c.511C>T p.R171W | Missense Mutation (SNP) | VAF 294/971 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767379547, COSV65500521; called by muse, mutect2, varscan2
- MPP5 | c.292G>A p.G98R | Missense Mutation (SNP) | VAF 40/742 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99906748; called by muse, mutect2
- NBPF4 | c.1436C>T p.A479V | Missense Mutation (SNP) | VAF 154/636 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1300813973, COSV101312713; called by muse, mutect2, varscan2
- RASIP1 | c.1099G>A p.D367N | Missense Mutation (SNP) | VAF 34/622 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV55803393; called by muse, mutect2
- SUMF2 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 89/185 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.501); catalogued as rs1318142006; called by muse, mutect2, varscan2
- TBC1D16 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 252/732 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as rs779276445, COSV100187686; called by muse, varscan2
- TGS1 | c.155G>A p.G52D | Missense Mutation (SNP) | VAF 52/782 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1316954974; called by muse, mutect2
- BMPER | c.1957G>A p.G653S | Missense Mutation (SNP) | VAF 48/506 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- LEMD3 | c.607G>C p.A203P | Missense Mutation (SNP) | VAF 32/622 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.205); called by muse, mutect2
- OR4K17 | c.25G>A p.V9M | Missense Mutation (SNP) | VAF 359/746 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- PPP4R3A | c.521T>A p.L174Q | Missense Mutation (SNP) | VAF 34/1290 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SNX14 | c.2148G>T p.E716D (on ENST00000314673 / NM_001350535.1; = p.E663D on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/736 reads (3%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2
- THADA | c.636G>T p.Q212H | Missense Mutation (SNP) | VAF 42/1408 reads (3%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.956); called by muse, mutect2
- ZSCAN20 | c.2516C>A p.A839D | Missense Mutation (SNP) | VAF 48/652 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.122); called by muse, mutect2
- ANKRD60 | c.603C>T p.T201= | Silent (SNP) | VAF 110/1131 reads (10%) | catalogued as rs555582751, COSV64518703; called by muse, mutect2
- EDIL3 | c.612G>A p.A204= | Silent (SNP) | VAF 100/1226 reads (8%) | catalogued as rs757759194, COSV99677957; called by muse, mutect2
- FLG | c.9957G>A p.P3319= | Silent (SNP) | VAF 284/777 reads (37%) | catalogued as rs774241945, COSV64242888; called by muse, varscan2
- LY9 | c.1710C>T p.G570= | Silent (SNP) | VAF 99/445 reads (22%) | catalogued as rs763678253, COSV54431972; called by muse, mutect2, varscan2
- MXRA8 | c.726C>T p.R242= | Silent (SNP) | VAF 45/847 reads (5%) | called by muse, mutect2
- PMPCB | c.159G>A p.L53= | Silent (SNP) | VAF 467/1340 reads (35%) | catalogued as COSV50788275; called by muse, mutect2, varscan2
- SH3GL1 | c.1002G>A p.T334= | Silent (SNP) | VAF 42/521 reads (8%) | catalogued as rs779758597, COSV53656394; called by muse, mutect2
- ABCA4 | c.*54C>T | 3'UTR (SNP) | VAF 29/892 reads (3%) | catalogued as rs962505043, COSV100933250; called by muse, mutect2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 18/366 reads (5%) | called by muse, mutect2
- ECI2 | c.-8C>G | 5'UTR (SNP) | VAF 123/312 reads (39%) | called by muse, mutect2, varscan2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 18/310 reads (6%) | called by muse, mutect2
- PXDNL | c.-16A>G | 5'UTR (SNP) | VAF 66/778 reads (8%) | called by muse, mutect2
- RNU6-1191P | chr16:81109268 G>A | 5'Flank (SNP) | VAF 126/1137 reads (11%) | catalogued as rs780673400; called by muse, mutect2, varscan2
